Surgical pathology report (de-identified scan), TCGA case TCGA-FV-A3R3, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-FV-A3R3-01A (Primary Tumor).

Sex:
D.O.B.:
MRN #:
Ref Phy:

Age

SPECIMEN INFO

Collected:
Received:
Reported:

SURGICAL PATHOLOGY REPORT

DIAGNOSIS

DIAGNOSIS:

Liver, partial hepatectomy:

Tumor Characteristics:

1. Histologic type: Hepatocellular carcinoma.
2. Histologic grade: Grade II (of III).
3. Tumor site: Right lobe of liver (involving regions 4 and 5).
4. Tumor size: 18.0 cm in greatest dimension.
5. Tumor focality: Unifocal.
6. Extent of invasion:
Tumor confined to liver.

7. Lymphovascular space invasion: Not identified.

Surgical Margin Status:

1. Parenchymal margin: Negative.

Other:

1. pTNM stage: pT1 NX.

Reviewed: [Signature]	3/21/12	3/21/12

Electronic Signature:

COMMENTS:

There is a hepatocellular neoplasm with prominent atypia involving the partial resection of liver. The neoplasm is positive for keratin CAM5.2 and Hepar. There is a focus positive for CK7. CK20 is negative. Reticulin stain show disruption of the reticulin fibers which are located predominantly in fibrovascular areas. The liver parenchyma in the non-tumor areas shows normal staining pattern with reticulin. There is no increase in staining with iron or trichrome. The neoplasm is a hepatocellular carcinoma. It does not have features of fibrolamellar type.

This case has been reviewed by [Signature]

who are in agreement with the diagnosis.

CLINICAL INFORMATION

CLINICAL HISTORY:

Preoperative Diagnosis: Right upper quadrant mass below liver

Postoperative Diagnosis:

Symptoms/Radiologic Findings:

ICD-O-3
carcinoma, hepatocellular, NOS
8170/3

SPECIMENS:

Liver mass

Site: liver c22.0

3-30-12 RD

SPECIMEN DATA

GROSS DESCRIPTION:

Specimen is received fresh labeled with the patient's name and consists of a 1.5 kilogram, 20.0 x 16.0 x 11.5 cm portion of liver received with attached gallbladder. The gallbladder is 11.5 x 6.5 x 3.0 cm. The serosa is purple-gray and glistening. On opening, the lumen contains dark green viscid bile along with multiple yellow-tan multifaceted choleliths aggregating to 7.5 x 3.0 x 1.5 cm. Some are present near the cystic duct. The liver is partially surfaced by pink-tan smooth and glistening to focally shaggy capsule. Exposed parenchyma is identified at the margin. This margin is inked, the specimen is serially sectioned to reveal an 18.0 x 12.0 x 9.5 cm encapsulated, nodular mass that abuts the liver capsule and approaches to within 1.5 cm of the inked parenchymal margin. This mass features a yellow-tan friable, focally hemorrhagic cut surface with areas of yellow-green discoloration. This mass is present at the gallbladder bed however invasion into the gallbladder is not present. Normal appearing pink-tan liver parenchyma is present near the margin. Additional masses are not identified. Representative sections are submitted for frozen section with the residual entirely resubmitted for permanent section in cassettes 1 and 2 labeled designated as follows: 1--tissue previously designated FSA1 (region 4B); 2--tissue previously designated FSA2 (region 5). Additional representative sections are submitted in cassettes 3-12 designated as follows: 3--cystic duct margin; 4 and 5--mass to gallbladder; 6--additional parenchymal margin, perpendicular; 7--mass to normal hepatic parenchyma and liver capsule; 8 and 9--additional mass to liver capsule; 10-12--additional mass. Additionally, a yellow green and blue cassette are submitted for research each labeled.

INTRA-OPERATIVE CONSULTATION:

FROZEN SECTION DIAGNOSES: FSA1 and A2: Hepatocellular neoplasm: tumor not identified on inked margin in representative sections per Dr.

Source: NCI Genomic Data Commons file d3b1c04a-d4a3-4d19-a9e7-1ec8885d58ce (TCGA-FV-A3R3.FF0E1601-BC87-4E61-95BE-1776C9F85002.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).